Somatic mutation profile of tumor specimen MP2PRT-PAPHXK-TMP1-A (aliquot MP2PRT-PAPHXK-TMP1-A-1-0-D-A83M-36) from MP2PRT case MP2PRT-PAPHXK, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.4 years (1,987 days).
Specimen MP2PRT-PAPHXK-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 210868f2-f803-4075-8a04-95a309a52517.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPHXK-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPHXK-NM1-A-1-0-D-A83M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/76849158-f546-4979-8f05-873332b882c5

The open-access MAF lists 24 somatic variants for this specimen: 18 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 5, Splice Region 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 19/185 reads (10%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); catalogued as rs121913527, COSV55501778, COSV55541748, COSV55727828; ClinVar: uncertain significance / pathogenic; called by muse, mutect2
- NRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 78/249 reads (31%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen benign (0.369); catalogued as rs121913250, CM136798, COSV54736487, COSV54736621, COSV54736940; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ASB4 | c.71C>T p.A24V | Missense Mutation (SNP) | VAF 136/268 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs749548166; called by muse, mutect2, varscan2
- CACNA1B | c.393C>T p.D131= | Splice Region (SNP) | VAF 66/163 reads (40%) | catalogued as rs774589225, COSV53113802; called by muse, mutect2, varscan2
- CEBPE | c.502G>A p.V168I | Missense Mutation (SNP) | VAF 114/324 reads (35%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.939); catalogued as rs371549805; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DOT1L | c.4505C>T p.P1502L | Missense Mutation (SNP) | VAF 180/389 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1281612667, COSV101288944; called by muse, mutect2, varscan2
- FGFR2 | c.1361C>T p.T454M | Missense Mutation (SNP) | VAF 29/529 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.241); catalogued as rs148672240; ClinVar: uncertain significance; called by muse, mutect2
- FHOD3 | c.3959C>T p.S1320L (on ENST00000359247 / NM_001281739.3; = p.S1337L on NM_025135.5) | Missense Mutation (SNP) | VAF 76/430 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.07); catalogued as COSV57182975; called by muse, mutect2, varscan2
- KLRC3 | c.146C>T p.S49F | Missense Mutation (SNP) | VAF 47/126 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV67250253, COSV67250893; called by muse, mutect2, varscan2
- PAX9 | c.1018G>A p.A340T | Missense Mutation (SNP) | VAF 61/187 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); catalogued as COSV100491028; called by muse, mutect2, varscan2
- PRKCA | c.1333G>A p.A445T | Missense Mutation (SNP) | VAF 80/250 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.75); catalogued as COSV52584118; called by muse, varscan2
- SI | c.1303C>T p.R435C | Missense Mutation (SNP) | VAF 14/168 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.978); catalogued as rs370325800, COSV104387962; called by muse, mutect2
- TDRD1 | c.2480G>A p.R827Q | Missense Mutation (SNP) | VAF 58/267 reads (22%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as rs374288064; called by muse, mutect2, varscan2
- CEP63 | c.932C>T p.P311L | Missense Mutation (SNP) | VAF 50/161 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ITPRID1 | c.2720C>T p.A907V | Missense Mutation (SNP) | VAF 20/197 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.225); called by muse, mutect2, varscan2
- KIF26B | c.5738C>T p.S1913L | Missense Mutation (SNP) | VAF 187/613 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- NSMAF | c.928C>G p.L310V | Missense Mutation (SNP) | VAF 102/233 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.042); called by muse, varscan2
- USH2A | c.4906G>A p.G1636S | Missense Mutation (SNP) | VAF 16/150 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AHNAK2 | c.12066C>T p.S4022= | Silent (SNP) | VAF 151/534 reads (28%) | catalogued as rs372712364, COSV60910675; called by muse, mutect2, varscan2
- ARHGAP39 | c.1665G>A p.A555= | Silent (SNP) | VAF 202/464 reads (44%) | catalogued as COSV52767017; called by muse, mutect2, varscan2
- HECW1 | c.321C>T p.D107= | Silent (SNP) | VAF 95/217 reads (44%) | catalogued as rs375404889; called by muse, mutect2, varscan2
- NYAP2 | c.846C>T p.D282= | Silent (SNP) | VAF 99/294 reads (34%) | catalogued as COSV56001691; called by muse, mutect2, varscan2
- SLC17A3 | c.498C>T p.C166= | Silent (SNP) | VAF 67/269 reads (25%) | called by muse, mutect2, varscan2
- MYO18B | chr22:26030912 ins TCAGCCCCGGTCCCCCTTTT | 3'Flank (INS) | VAF 34/133 reads (26%) | called by mutect2, pindel, varscan2
